Somatic mutation profile of tumor specimen TCGA-P4-A5EA-01A (aliquot TCGA-P4-A5EA-01A-11D-A28G-10) from TCGA case TCGA-P4-A5EA, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 54.1 years (19,748 days).
Specimen TCGA-P4-A5EA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 782667cb-8ed5-4754-8642-46495cbfeb4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P4-A5EA-11A (Solid Tissue Normal), aliquot TCGA-P4-A5EA-11A-11D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e06bcb0-5619-4524-ae78-371a019753f1

The open-access MAF lists 66 somatic variants for this specimen: 53 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Frame Shift Del 12, Silent 12, In Frame Del 3, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF2 | c.810+1G>A p.X270_splice | Splice Site (SNP) | VAF 12/38 reads (32%) | catalogued as rs794728682, COSV58528767; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C15orf39 | c.2449A>G p.K817E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as COSV62297734; called by muse, mutect2
- CAMK1D | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV66617840; called by muse, mutect2
- CD59 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.746); catalogued as COSV60919754; called by muse, mutect2, varscan2
- CD96 | c.673C>T p.L225F (on ENST00000283285 / NM_198196.3; = p.L209F on NM_005816.5) | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV51920873; called by muse, mutect2
- CDH8 | c.1398C>G p.I466M | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV54865781, COSV54890393; called by muse, mutect2
- CREBBP | c.3148G>T p.E1050* | Nonsense Mutation (SNP) | VAF 27/102 reads (26%) | catalogued as COSV52136246; called by muse, mutect2, varscan2
- CSMD2 | c.8141G>T p.G2714V | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.98); PolyPhen probably damaging (0.96); catalogued as rs182823482, COSV53947974; called by mutect2, varscan2
- DSCAML1 | c.2734C>G p.L912V (on ENST00000321322; = p.L852V on NM_020693.4) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); catalogued as COSV58399784; called by muse, mutect2, varscan2
- FCHO2 | c.1414C>A p.L472I | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.874); catalogued as rs1029226028, COSV59276183; called by muse, mutect2, varscan2
- GATAD2B | c.367C>G p.P123A | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV64085581; called by muse, mutect2
- GGA3 | c.508G>C p.D170H (on ENST00000537686 / NM_138619.4; = p.D137H on NM_014001.5) | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55458447; called by muse, mutect2, varscan2
- GOLGA4 | c.1703_1704del p.X568_splice | Splice Site (DEL) | VAF 23/121 reads (19%) | catalogued as rs1304791639; called by pindel, varscan2
- IKZF5 | c.499A>G p.K167E | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV64397912; called by muse, mutect2
- IL10RA | c.851G>T p.R284L | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57141817; called by muse, mutect2, varscan2
- MAEA | c.932G>A p.S311N (on ENST00000303400 / NM_001017405.3; = p.S270N on NM_005882.5) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1490986050, COSV53264300; called by muse, mutect2, varscan2
- MAP3K1 | c.4154_4155insTA p.R1385Sfs*38 | Frame Shift Ins (INS) | VAF 14/110 reads (13%) | catalogued as COSV101267013; called by mutect2, pindel, varscan2
- MAP3K6 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV62889555; called by muse, mutect2, varscan2
- MTRF1L | c.621G>C p.K207N | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV65873900; called by muse, mutect2, varscan2
- MUC16 | c.28730C>G p.S9577* | Nonsense Mutation (SNP) | VAF 28/142 reads (20%) | catalogued as COSV67484605; called by muse, mutect2, varscan2
- NFKBIZ | c.976del p.L326Sfs*15 | Frame Shift Del (DEL) | VAF 15/87 reads (17%) | catalogued as COSV58201357; called by mutect2, pindel, varscan2
- PHTF1 | c.741_742del p.K250Sfs*11 | Frame Shift Del (DEL) | VAF 15/78 reads (19%) | catalogued as rs752774650; called by mutect2, pindel, varscan2
- PRKCG | c.1265C>G p.S422C | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.453); catalogued as COSV54731484; called by muse, mutect2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, varscan2
- RPH3AL | c.366A>T p.K122N | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58746378; called by muse, mutect2, varscan2
- RPL26 | c.200T>G p.I67S | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV53447457; called by muse, mutect2
- THOC2 | c.3466A>G p.K1156E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55553351; called by muse, mutect2, varscan2
- TNFRSF19 | c.179A>C p.K60T | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50318270; called by muse, mutect2, varscan2
- TOM1 | c.675G>T p.E225D | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV65899319; called by muse, mutect2, varscan2
- TOM1 | c.676A>C p.M226L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV65899330; called by muse, mutect2, varscan2
- TPP2 | c.3645G>T p.W1215C | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.258); catalogued as COSV65754303; called by muse, mutect2
- TRIM32 | c.1610T>A p.L537Q | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV57808262; called by muse, mutect2, varscan2
- TRIM68 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.19); catalogued as rs771578609, COSV56169585; called by muse, mutect2, varscan2
- TSPAN15 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.073); catalogued as rs143260694; called by muse, mutect2, varscan2
- UBE2I | c.348A>G p.I116M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV57646519; called by muse, mutect2
- UNC79 | c.2815G>C p.D939H (on ENST00000393151 / NM_001346218.2; = p.D762H on NM_020818.5) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV56375943, COSV56404644; called by muse, mutect2, varscan2
- UTP20 | c.3095C>A p.S1032Y | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55383338, COSV99881605; called by muse, mutect2, varscan2
- ZIC1 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 33/153 reads (22%) | catalogued as COSV51556790; called by muse, mutect2, varscan2
- AAGAB | c.478A>G p.K160E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.672); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.7836_7837del p.G2613Kfs*56 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by pindel, varscan2
- ARHGAP5 | c.2111_2114del p.R704Ifs*26 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, varscan2
- CEP128 | c.2166_2169del p.F722Lfs*14 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | called by mutect2, pindel, varscan2
- EPHA2 | c.2007_2008insCA p.F670Hfs*10 | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- GLCE | c.727_728del p.D243Qfs*5 | Frame Shift Del (DEL) | VAF 17/100 reads (17%) | called by pindel, varscan2
- MTA2 | c.815_816del p.E272Gfs*5 | Frame Shift Del (DEL) | VAF 18/124 reads (15%) | called by pindel, varscan2
- NASP | c.471_491del p.K158_S164del | In Frame Del (DEL) | VAF 23/197 reads (12%) | called by mutect2, pindel
- PCDHB5 | c.118_119del p.E40Kfs*38 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, varscan2
- PCED1A | c.808_816del p.G270_E272del | In Frame Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel
- RASA1 | c.433_434del p.P145Ffs*12 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- SPIRE2 | c.1183_1184del p.D395Cfs*21 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | called by mutect2, varscan2
- TEX33 | c.507_509del p.D169del (on ENST00000381821 / NM_001163857.2; = p.D84del on NM_178552.4) | In Frame Del (DEL) | VAF 20/78 reads (26%) | called by pindel, varscan2
- TTL | c.725_726del p.N242Tfs*15 | Frame Shift Del (DEL) | VAF 31/121 reads (26%) | called by mutect2, pindel, varscan2
- ZNF7 | c.377_378del p.S126* | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | called by mutect2, pindel, varscan2
- AUTS2 | c.1635G>A p.P545= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs757756875, COSV61399821; called by muse, mutect2, varscan2
- CTAGE1 | c.1827C>G p.L609= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as COSV66944283; called by muse, mutect2
- DGKK | c.1404A>G p.K468= | Silent (SNP) | VAF 83/328 reads (25%) | catalogued as COSV65709123; called by muse, mutect2, varscan2
- GCN1 | c.7263C>G p.A2421= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV56107090, COSV56107101, COSV56113233; called by muse, mutect2, varscan2
- HMGB1 | c.378G>A p.A126= | Silent (SNP) | VAF 4/71 reads (6%) | catalogued as rs1248991681, COSV58104418; called by muse, mutect2
- IL17RC | c.174C>T p.S58= | Silent (SNP) | VAF 19/186 reads (10%) | catalogued as COSV55970263; called by muse, mutect2
- LAMC3 | c.1011G>A p.T337= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs201170354, COSV63091964; called by muse, mutect2, varscan2
- PPP6R1 | c.2331A>C p.S777= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV58985000; called by muse, mutect2
- SRCAP | c.6288A>G p.E2096= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV52678788; called by muse, mutect2, varscan2
- TLL1 | c.2289T>C p.H763= | Silent (SNP) | VAF 17/150 reads (11%) | catalogued as COSV50290649; called by muse, mutect2, varscan2
- TUFT1 | c.939A>G p.K313= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV61950037; called by muse, mutect2, varscan2
- ZNF257 | c.744G>A p.K248= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV71311075; called by muse, mutect2, varscan2
- SLC48A1 | c.*118A>T | 3'UTR (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
